Somatic mutation profile of tumor specimen TCGA-3N-A9WD-06A (aliquot TCGA-3N-A9WD-06A-11D-A38G-08) from TCGA case TCGA-3N-A9WD, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 83.1 years (30,346 days).
Specimen TCGA-3N-A9WD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f820973-3d28-43fd-a20f-aebd52ecb694.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3N-A9WD-10A (Blood Derived Normal), aliquot TCGA-3N-A9WD-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9c5be64-da8a-4458-852e-522590f5c3b1

The open-access MAF lists 1,100 somatic variants for this specimen: 727 protein-altering or splice-affecting, 349 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 663, Silent 349, Nonsense Mutation 41, Splice Site 9, RNA 9, Intron 7, Splice Region 6, Frame Shift Del 4, 5'Flank 4, Frame Shift Ins 2, Translation Start Site 2, 3'UTR 2.

Variants (750 of 1,100; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRNKL1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 16/70 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1057519885, COSV55618331; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CYP4V2 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199476187, CM056576, COSV101114913; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 47/119 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PRLR | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 21/116 reads (18%) | catalogued as rs376188691, COSV51492949; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.421T>G p.C141G | Missense Mutation (SNP) | VAF 12/37 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519978, COSV52675559, COSV52751154, COSV52796306, COSV53037181; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.893); catalogued as COSV100229108; called by muse, mutect2, varscan2
- ABCA10 | c.2680C>T p.P894S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763677848, COSV52229715; called by muse, mutect2, varscan2
- ABCB1 | c.3011C>T p.S1004L | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV99713399; called by muse, mutect2, varscan2
- ABCC6 | c.1930C>T p.P644S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as COSV52743045, COSV52747777, COSV99229346; called by mutect2, varscan2
- ABCC6 | c.1125G>T p.K375N | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV99229055; called by muse, mutect2, varscan2
- ABCC9 | c.3971A>T p.N1324I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV99686138; called by muse, mutect2, varscan2
- AC008676.3 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV100400449; called by muse, mutect2, varscan2
- AC100868.1 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99226294; called by muse, mutect2, varscan2
- ACER1 | c.489G>A p.K163= | Splice Region (SNP) | VAF 15/51 reads (29%) | catalogued as COSV100034047; called by muse, mutect2, varscan2
- ACTR6 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99498667; called by muse, mutect2, varscan2
- ADAM28 | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765204427, COSV56102242, COSV56105258; called by muse, mutect2, varscan2
- ADAMTS18 | c.2335A>T p.I779F | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.303); catalogued as COSV99273318; called by muse, mutect2, varscan2
- ADAMTS8 | c.2559G>T p.Q853H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV99961138; called by muse, mutect2, varscan2
- ADAMTSL4 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99647523; called by muse, mutect2, varscan2
- ADCK2 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV99301693; called by muse, mutect2
- ADCY1 | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV52032049; called by muse, mutect2, varscan2
- ADGRB3 | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.993); catalogued as rs778148344, COSV65396928; called by muse, mutect2, varscan2
- ADGRB3 | c.4381G>A p.E1461K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53234602; called by mutect2, varscan2
- ADGRF4 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1356026618, COSV51955644, COSV99348560; called by muse, mutect2, varscan2
- ADGRG4 | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs866409405, COSV99795898; called by muse, mutect2, varscan2
- ADGRG4 | c.6731C>T p.S2244F | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV54951468; called by muse, mutect2
- ADGRL3 | c.1687G>A p.E563K (on ENST00000506720 / NM_001322402.2; = p.E495K on NM_015236.6) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as rs759065083, COSV72229254; called by muse, mutect2, varscan2
- ADH1C | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV72463418; called by muse, varscan2
- ADH1C | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV101565189; called by muse, varscan2
- ADH1C | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV72463461; called by muse, mutect2, varscan2
- ADH6 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV99422537; called by muse, mutect2, varscan2
- AFP | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV56924656; called by mutect2, varscan2
- AHNAK | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.435); catalogued as COSV99948125; called by muse, mutect2, varscan2
- AKAP3 | c.2320C>T p.Q774* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99962292; called by muse, mutect2, varscan2
- AKR1C4 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99578765; called by muse, mutect2, varscan2
- ALDOA | c.1016A>G p.N339S (on ENST00000642816 / NM_001243177.4; = p.N285S on NM_184041.5) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs543994647, COSV100582127; called by muse, mutect2, varscan2
- AMER2 | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100766310; called by muse, mutect2, varscan2
- AMOTL1 | c.1718A>G p.D573G | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100504512; called by muse, mutect2, varscan2
- ANGPT1 | c.1172G>A p.R391K | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.029); catalogued as COSV99863276; called by muse, mutect2, varscan2
- ANKFN1 | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV59440257; called by muse, mutect2, varscan2
- ANKRD30A | c.3385G>A p.E1129K (on ENST00000611781; = p.E1073K on NM_052997.2) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV64607971; called by muse, mutect2, varscan2
- ANKRD30A | c.3837G>T p.L1279F (on ENST00000611781; = p.L1223F on NM_052997.2) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV64608865; called by muse, varscan2
- ANLN | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV99732482; called by muse, mutect2, varscan2
- ANO4 | c.628C>T p.R210W (on ENST00000392977 / NM_001286615.2; = p.R175W on NM_178826.4) | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.719); catalogued as rs372521580; called by muse, mutect2, varscan2
- APBB1IP | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100770907; called by muse, mutect2, varscan2
- APOB | c.4162C>T p.R1388C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as rs267599185, COSV51928488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AR | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM940087, COSV65957288; called by muse, mutect2, varscan2
- ARAP2 | c.3466C>T p.P1156S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as rs771667374, COSV100394865; called by muse, mutect2, varscan2
- ARAP2 | c.3334G>A p.G1112S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1318159151, COSV100394866; called by muse, mutect2, varscan2
- ARHGAP27 | c.1495A>C p.K499Q (on ENST00000428638 / NM_001282290.1; = p.K158Q on NM_199282.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100976553; called by muse, mutect2, varscan2
- ARHGAP33 | c.2621C>T p.P874L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1238304246, COSV99137519; called by muse, mutect2, varscan2
- ARHGAP33 | c.2953C>T p.P985S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.472); catalogued as COSV99138820; called by muse, mutect2, varscan2
- ARHGAP33 | c.3068C>T p.S1023F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs751041631, COSV99138826; called by mutect2, varscan2
- ARHGAP39 | c.2189C>T p.P730L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99431654; called by muse, mutect2, varscan2
- ARMC4 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53462302; called by muse, mutect2
- ARMC9 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63021096; called by muse, mutect2, varscan2
- ARPP21 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99492391; called by muse, mutect2, varscan2
- ARR3 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100330906; called by muse, mutect2, varscan2
- ATAD2 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs945838795, COSV99784872; called by muse, mutect2, varscan2
- ATF6 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100909296; called by muse, mutect2, varscan2
- ATP10B | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs201710345; called by muse, mutect2, varscan2
- B3GNT7 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99805950; called by muse, mutect2, varscan2
- B4GALNT4 | c.2846G>A p.G949E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV57324399; called by muse, mutect2, varscan2
- BAHCC1 | c.7030C>T p.R2344C | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1163257997; called by muse, mutect2
- BBOX1 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as rs769667333, COSV99589780; called by mutect2, varscan2
- BCKDK | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV99570716; called by muse, mutect2, varscan2
- BPIFA1 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV100845647; called by muse, mutect2, varscan2
- BPIFA3 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV100967079; called by muse, mutect2, varscan2
- BRSK2 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs752855575, COSV100372844; called by muse, mutect2, varscan2
- BRWD3 | c.5089C>G p.R1697G | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.238); catalogued as COSV100956226; called by muse, mutect2, varscan2
- C12orf50 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.568); catalogued as rs759969576, COSV53896713; called by muse, mutect2, varscan2
- C12orf54 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV100011527; called by muse, mutect2, varscan2
- C1QTNF9 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs779386798, COSV59656776; called by muse, mutect2, varscan2
- C1QTNF9 | c.228A>T p.R76= | Splice Region (SNP) | VAF 16/99 reads (16%) | catalogued as COSV100129945; called by muse, mutect2, varscan2
- C3orf56 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV101228968; called by muse, mutect2, varscan2
- C6 | c.1890G>A p.M630I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs866261314, COSV54715552; called by muse, mutect2, varscan2
- C6 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.411); catalogued as rs763257632, COSV54704717; called by muse, mutect2, varscan2
- C6orf201 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.048); catalogued as COSV100326577; called by muse, mutect2, varscan2
- C9orf135 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV65874439; called by muse, mutect2, varscan2
- CA2 | c.663+2T>C p.X221_splice | Splice Site (SNP) | VAF 16/134 reads (12%) | catalogued as COSV99570141; called by muse, mutect2, varscan2
- CA4 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.268); catalogued as rs753005580, COSV56280848; called by muse, mutect2, varscan2
- CAPN13 | c.1711G>A p.V571I | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV104400414, COSV99700411; called by muse, mutect2, varscan2
- CASQ1 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100850164; called by muse, mutect2, varscan2
- CASS4 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV100824765; called by muse, mutect2, varscan2
- CATSPERD | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs369818912; called by muse, mutect2, varscan2
- CATSPERG | c.2939G>A p.S980N | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99286652; called by muse, mutect2, varscan2
- CCDC141 | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs914187336, COSV55370770; called by muse, mutect2, varscan2
- CCDC74B | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.591); catalogued as rs756608401, COSV100134551; called by muse, mutect2, varscan2
- CCDC88C | c.5210C>G p.A1737G | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100484960, COSV57796106; called by muse, mutect2, varscan2
- CCN4 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.458); catalogued as rs760043627, COSV51530809; called by muse, mutect2, varscan2
- CCS | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100040052; called by muse, varscan2
- CCSER1 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100393330; called by muse, mutect2, varscan2
- CCSER1 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757167041, COSV100393331; called by muse, mutect2, varscan2
- CD163 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373039092; called by muse, mutect2, varscan2
- CD163 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.718); catalogued as COSV100775948; called by muse, mutect2
- CD163L1 | c.4015G>A p.E1339K | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1181085302, COSV58024349; called by muse, mutect2, varscan2
- CD163L1 | c.1012C>T p.L338F | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100550263; called by muse, mutect2, varscan2
- CD226 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); catalogued as COSV99711230; called by muse, mutect2, varscan2
- CD226 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.744); catalogued as rs377159737, COSV54617164; called by muse, mutect2, varscan2
- CDC42BPG | c.3223C>T p.P1075S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as COSV61345345; called by muse, mutect2, varscan2
- CDH11 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.527); catalogued as COSV51761439; called by muse, mutect2, varscan2
- CDH13 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.954); catalogued as COSV99227356; called by muse, mutect2, varscan2
- CDH13 | c.1214G>A p.G405E | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99227361; called by muse, mutect2, varscan2
- CDH17 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV99217584; called by muse, mutect2, varscan2
- CDH17 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99217585; called by muse, mutect2
- CEACAM21 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV51813806; called by muse, mutect2, varscan2
- CEACAM5 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.857); catalogued as COSV55751337; called by muse, mutect2, varscan2
- CENPJ | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV101121528; called by muse, mutect2, varscan2
- CEP128 | c.2794C>T p.R932C | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs773597804, COSV55378656; called by muse, mutect2, varscan2
- CEP68 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765429744, COSV53127187, COSV99561025; called by muse, mutect2, varscan2
- CFAP299 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866257430, COSV63880963; called by muse, mutect2, varscan2
- CFAP69 | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100290231; called by muse, varscan2
- CFAP97 | c.310T>G p.C104G | Missense Mutation (SNP) | VAF 2/18 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99703486; called by muse, mutect2
- CFLAR | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 24/105 reads (23%) | catalogued as COSV100009513; called by muse, mutect2, varscan2
- CHCHD4 | c.359C>T p.P120L (on ENST00000396914 / NM_001098502.2; = p.P133L on NM_144636.3) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99853963; called by muse, mutect2, varscan2
- CHERP | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52227808, COSV99550343; called by muse, mutect2, varscan2
- CLCN4 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); catalogued as COSV101073897; called by muse, mutect2, varscan2
- CLDN12 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs752426881, COSV55308112; called by muse, mutect2, varscan2
- CLEC10A | c.670G>A p.E224K (on ENST00000254868 / NM_182906.4; = p.E200K on NM_006344.4) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99644759; called by muse, mutect2, varscan2
- CLEC4F | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV55479695; called by muse, mutect2, varscan2
- CLEC5A | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.63); catalogued as rs782619429, COSV101407776, COSV69397071; called by muse, mutect2, varscan2
- CLTCL1 | c.4892C>T p.P1631L (on ENST00000427926 / NM_007098.4; = p.P1574L on NM_001835.4) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs782615518, COSV99310996; called by muse, mutect2, varscan2
- CLTRN | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.509); catalogued as rs1368367427, COSV66711890; called by muse, mutect2, varscan2
- CLVS1 | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs754940374, COSV57981303; called by muse, mutect2, varscan2
- CMYA5 | c.4996G>A p.D1666N | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV101484154, COSV71409626; called by muse, mutect2
- CMYA5 | c.9886G>A p.E3296K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV71405938; called by muse, mutect2, varscan2
- COBLL1 | c.3355A>T p.N1119Y (on ENST00000392717; = p.N1081Y on NM_014900.5) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV99528197; called by muse, mutect2
- COL11A1 | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100617135; called by muse, mutect2
- COL1A2 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.709); catalogued as COSV99800206; called by muse, mutect2, varscan2
- COL3A1 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs1385617008, COSV100483250, COSV100483977; called by muse, mutect2, varscan2
- COL3A1 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV100483253; called by muse, mutect2, varscan2
- COL4A1 | c.1382-1G>A p.X461_splice | Splice Site (SNP) | VAF 10/29 reads (34%) | catalogued as CS130946, COSV101011279; called by muse, mutect2, varscan2
- COL4A2 | c.4228C>T p.R1410* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as rs752813292, COSV100847392; called by muse, mutect2, varscan2
- COL4A5 | c.1784G>A p.G595E | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.489); catalogued as COSV100088224; called by muse, mutect2, varscan2
- COL5A1 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100880091; called by muse, mutect2
- CORO2B | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.124); catalogued as COSV55951550, COSV99963413; called by muse, mutect2
- CREB3L1 | c.597G>A p.E199= | Splice Region (SNP) | VAF 12/67 reads (18%) | catalogued as COSV99915115; called by muse, mutect2, varscan2
- CREB3L3 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs138185635; called by muse, mutect2, varscan2
- CRISP2 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV59256789; called by muse, mutect2, varscan2
- CRISP3 | c.214G>A p.E72K (on ENST00000371159 / NM_001368123.1; = p.E54K on NM_006061.4) | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.672); catalogued as rs866284987, COSV99539026; called by muse, mutect2, varscan2
- CRYBG1 | c.5888G>A p.G1963E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100954540; called by muse, mutect2, varscan2
- CSMD1 | c.10584C>A p.N3528K (on ENST00000520002; = p.N3527K on NM_033225.6) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV100149933; called by mutect2, varscan2
- CSMD1 | c.10508C>T p.S3503L (on ENST00000520002; = p.S3502L on NM_033225.6) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV100144841, COSV59325755; called by muse, mutect2
- CSMD1 | c.5621C>T p.S1874L (on ENST00000520002; = p.S1873L on NM_033225.6) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100149943; called by muse, mutect2
- CSMD1 | c.3069T>G p.F1023L (on ENST00000520002; = p.F1022L on NM_033225.6) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100149953; called by muse, mutect2
- CSMD1 | c.1629T>A p.S543R (on ENST00000520002; = p.S542R on NM_033225.6) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.995); catalogued as COSV59411057; called by muse, mutect2
- CSMD2 | c.5186G>A p.R1729Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.185); catalogued as COSV53910930; called by muse, mutect2, varscan2
- CSTF3 | c.1020G>A p.M340I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV100124138; called by muse, mutect2, varscan2
- CTAGE6 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs779951636, COSV69916572, COSV69917874; called by muse, mutect2, varscan2
- CTPS2 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV100826927; called by muse, mutect2, varscan2
- CWH43 | c.2041G>A p.G681R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99893592; called by muse, mutect2, varscan2
- CYLD | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100282563; called by muse, mutect2, varscan2
- CYP2C9 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1207174374, COSV53247711; called by muse, varscan2
- CYP2C9 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs749300923, COSV99582833; called by muse, varscan2
- CYP2E1 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53312370; called by muse, mutect2
- CYP3A43 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55935263; called by muse, mutect2, varscan2
- CYP7B1 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as rs267601965, COSV59582493; called by muse, mutect2, varscan2
- DAB1 | c.1366C>T p.P456S (on ENST00000371231; = p.P423S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.65); catalogued as COSV100976425; called by muse, mutect2
- DAGLA | c.2881C>T p.R961C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs148445541, COSV99944492; called by muse, mutect2, varscan2
- DAZAP1 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs201791219, COSV99245339; called by muse, varscan2
- DCAF4L1 | c.785G>A p.W262* | Nonsense Mutation (SNP) | VAF 21/101 reads (21%) | catalogued as COSV100295809; called by muse, mutect2, varscan2
- DCC | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200830938; called by muse, mutect2, varscan2
- DCC | c.3130G>A p.V1044M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV100501090; called by muse, mutect2, varscan2
- DCDC1 | c.2018C>T p.S673F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs267602844, COSV60853388; called by muse, mutect2, varscan2
- DCUN1D3 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100176928; called by muse, mutect2, varscan2
- DDX60 | c.3322G>A p.E1108K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV101190508; called by muse, mutect2, varscan2
- DEF8 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as rs763930288, COSV51922125; called by muse, mutect2, varscan2
- DENND4A | c.2603A>G p.Y868C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV101475374; called by muse, mutect2
- DGKK | c.3049C>T p.Q1017* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV101052934; called by muse, mutect2, varscan2
- DGKK | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV101053085; called by muse, mutect2, varscan2
- DGLUCY | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV99824429; called by muse, mutect2, varscan2
- DIAPH1 | c.1252C>T p.L418F | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99526803; called by muse, mutect2, varscan2
- DLG2 | c.2141G>A p.R714K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99717137; called by muse, mutect2
- DLG2 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV99717142; called by muse, mutect2, varscan2
- DLG2 | c.1660G>T p.G554W | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99717150; called by muse, mutect2, varscan2
- DNAH10 | c.7667G>A p.R2556K (on ENST00000409039; = p.R2495K on NM_207437.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as COSV68990864, COSV68994001; called by muse, mutect2, varscan2
- DNAH3 | c.12309G>A p.W4103* | Nonsense Mutation (SNP) | VAF 22/130 reads (17%) | catalogued as COSV99768416; called by muse, mutect2, varscan2
- DNAH3 | c.10569T>G p.F3523L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99768419; called by muse, mutect2, varscan2
- DNAH3 | c.3821G>A p.R1274Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs777984798, COSV54506633; called by muse, mutect2, varscan2
- DNAH5 | c.12314G>A p.G4105E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99451130; called by muse, mutect2
- DNAH7 | c.9467C>T p.S3156L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100415915; called by muse, mutect2, varscan2
- DNAH7 | c.8518G>A p.E2840K | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV56753749; called by muse, mutect2, varscan2
- DNAJC21 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV100331478; called by muse, mutect2, varscan2
- DNMT3L | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV54263977; called by muse, mutect2, varscan2
- DOCK2 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56968130; called by muse, mutect2, varscan2
- DOCK3 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.892); catalogued as rs1326141503, COSV99813058; called by muse, mutect2, varscan2
- DOCK6 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99371037; called by muse, mutect2, varscan2
- DOK6 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV66925373; called by muse, mutect2
- DQX1 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs1241432586, COSV101099058; called by muse, mutect2, varscan2
- DRG2 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99233335; called by muse, mutect2, varscan2
- DSC2 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99199705; called by muse, mutect2, varscan2
- DSC3 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1402804256, COSV64572387; called by muse, mutect2, varscan2
- DSG1 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57134255; called by muse, mutect2, varscan2
- DSG1 | c.2536A>T p.T846S | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.018); catalogued as COSV99936181; called by muse, mutect2, varscan2
- DSG1 | c.2537C>T p.T846I | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99936184; called by muse, mutect2, varscan2
- DYNLRB2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV100009784; called by muse, mutect2, varscan2
- EDAR | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51500538; called by muse, mutect2, varscan2
- EFCAB13 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV58953208; called by muse, mutect2, varscan2
- ELFN2 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as rs780661723, COSV101297573; called by muse, mutect2, varscan2
- ELSPBP1 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV60413910; called by muse, mutect2, varscan2
- EMB | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as rs866302109, COSV57482353; called by muse, mutect2
- EML4 | c.1301T>G p.F434C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as COSV100580959; called by muse, mutect2, varscan2
- ENAM | c.1762C>G p.P588A | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.329); catalogued as rs149033201, COSV101253175; called by muse, mutect2, varscan2
- ENAM | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.22); catalogued as rs768681939, COSV101253177; called by muse, mutect2, varscan2
- EPB41L3 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as rs1283679414, COSV100549552; called by muse, mutect2, varscan2
- EPB41L4A | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 22/124 reads (18%) | catalogued as rs201980333, COSV54877724; called by muse, mutect2, varscan2
- EPG5 | c.6652C>T p.H2218Y | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.49); catalogued as COSV99957559; called by muse, mutect2, varscan2
- ERBB4 | c.3561A>C p.E1187D | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.078); catalogued as COSV100726272; called by muse, mutect2, varscan2
- ESR1 | c.741A>C p.E247D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99239727; called by muse, mutect2, varscan2
- ESR2 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV99963435; called by muse, mutect2, varscan2
- ESYT1 | c.2592+1G>A p.X864_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99920057; called by muse, mutect2, varscan2
- EXD1 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); catalogued as COSV100153703; called by muse, mutect2, varscan2
- EXOC5 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100567145; called by muse, mutect2, varscan2
- EXPH5 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56207978; called by muse, mutect2, varscan2
- F2RL3 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs770262883, COSV99935315; called by muse, varscan2
- FAM135B | c.2549G>A p.G850E | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.058); catalogued as rs370460671, COSV52731262; called by muse, mutect2, varscan2
- FAM153A | c.894G>A p.W298* | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100647063; called by mutect2, varscan2
- FAM171A1 | c.2015C>T p.S672F | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV100968325; called by muse, mutect2
- FAM171A1 | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs751970732, COSV100968328; called by muse, mutect2, varscan2
- FAM189A2 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs143765985; called by muse, mutect2, varscan2
- FAM47B | c.1276G>T p.E426* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100264384; called by muse, mutect2, varscan2
- FAM71B | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as COSV100262166; called by muse, mutect2, varscan2
- FAT2 | c.3442G>A p.E1148K | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768245088, COSV99943320; called by muse, mutect2, varscan2
- FAT2 | c.2417T>A p.L806Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99943323; called by muse, mutect2, varscan2
- FAT4 | c.5704C>T p.R1902* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as rs1474952333, COSV58673589; called by muse, mutect2, varscan2
- FBLN7 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.166); catalogued as COSV100485606; called by muse, mutect2, varscan2
- FCRL5 | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.903); catalogued as COSV62514007; called by muse, mutect2, varscan2
- FCSK | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1208947667, COSV99851000; called by muse, mutect2, varscan2
- FIGN | c.1281G>A p.M427I | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60768786; called by muse, mutect2, varscan2
- FILIP1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99385233; called by muse, mutect2, varscan2
- FLG | c.11483C>T p.S3828L | Missense Mutation (SNP) | VAF 151/341 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs774898663, COSV64238987; called by muse, mutect2, varscan2
- FLG | c.9353G>C p.R3118T | Missense Mutation (SNP) | VAF 149/346 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100911692; called by muse, mutect2, varscan2
- FLG | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs751519390, COSV64236489; called by muse, mutect2, varscan2
- FLNB | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs776030392, COSV99913721; called by muse, mutect2, varscan2
- FLRT2 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58138366; called by muse, mutect2, varscan2
- FLT1 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.765); catalogued as COSV56743444; called by muse, varscan2
- FLT4 | c.737A>T p.E246V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99987551; called by muse, mutect2, varscan2
- FMN2 | c.3127C>T p.P1043S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.456); catalogued as COSV60432596; called by muse, varscan2
- FOXD4L5 | c.283A>G p.R95G | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV101073193; called by muse, mutect2, varscan2
- FOXL1 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.886); catalogued as rs750324359, COSV100206321; called by muse, mutect2, varscan2
- FRAS1 | c.4021C>T p.P1341S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV53635555; called by muse, mutect2, varscan2
- FREM2 | c.6142C>T p.R2048W | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs768764795, COSV99749316; called by muse, mutect2, varscan2
- FRYL | c.5486C>T p.S1829F | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99977308; called by muse, mutect2, varscan2
- G6PC3 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs911423195, COSV99291275; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRA1 | c.1126A>C p.T376P | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV99196007; called by muse, mutect2, varscan2
- GABRA2 | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV62915135; called by muse, mutect2, varscan2
- GABRA2 | c.748A>T p.I250F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100734450; called by muse, mutect2, varscan2
- GABRB1 | c.948T>A p.F316L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99782150; called by muse, mutect2, varscan2
- GABRB2 | c.1195G>A p.D399N (on ENST00000274547; = p.D361N on NM_000813.3) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.271); catalogued as COSV50934953; called by muse, mutect2, varscan2
- GABRG2 | c.938G>A p.G313E (on ENST00000361925 / NM_001375343.1; = p.G273E on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100729748; called by muse, mutect2, varscan2
- GABRR3 | c.1001T>G p.L334R | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101512307; called by muse, mutect2, varscan2
- GALNT1 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.151); catalogued as COSV99322272; called by muse, mutect2, varscan2
- GALNTL6 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV101487788; called by muse, mutect2, varscan2
- GAP43 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs759584991, COSV100525693; called by muse, mutect2, varscan2
- GGH | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.234); catalogued as COSV99478862; called by muse, mutect2
- GGT7 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60539971; called by muse, mutect2, varscan2
- GHR | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); catalogued as COSV50118552; called by muse, mutect2, varscan2
- GIMAP2 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV99785410; called by muse, mutect2
- GIMAP6 | c.865A>T p.K289* | Nonsense Mutation (SNP) | VAF 5/82 reads (6%) | catalogued as COSV100188281; called by muse, mutect2
- GIMAP6 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.092); catalogued as rs145493080, COSV100188297; called by muse, mutect2, varscan2
- GLB1L3 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.484); catalogued as COSV101345141, COSV101345152; called by muse, mutect2, varscan2
- GON4L | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99674778; called by muse, mutect2, varscan2
- GPC5 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV65580031; called by muse, varscan2
- GPR39 | c.84G>A p.W28* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100257978; called by muse, mutect2, varscan2
- GPR83 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as COSV54717775; called by muse, mutect2, varscan2
- GPX6 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as COSV100724865; called by muse, mutect2, varscan2
- GRIA1 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV53596808, COSV53598294; called by muse, mutect2, varscan2
- GRIA1 | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.434); catalogued as COSV99600734; called by muse, mutect2, varscan2
- GRIA2 | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV52381735; called by muse, mutect2, varscan2
- GRID2 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV56263040, COSV99942500; called by muse, mutect2, varscan2
- GRIN2A | c.3154C>T p.L1052F | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58033914, COSV58050799, COSV58061393; called by muse, varscan2
- GRIN3A | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs767070992, COSV62450727; called by muse, mutect2, varscan2
- GRM4 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65217489; called by muse, mutect2, varscan2
- GTF3C1 | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as rs199881803, COSV100649528; called by muse, mutect2, varscan2
- GUCY1A2 | c.1948G>A p.G650R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV99975232; called by muse, mutect2, varscan2
- GUCY1A2 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as rs749940015, COSV99975245; called by muse, mutect2, varscan2
- GYPA | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs371519566; called by muse, mutect2, varscan2
- H2AC1 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV51237342; called by muse, mutect2, varscan2
- HABP2 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); catalogued as COSV100667976; called by muse, mutect2
- HCAR2 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV100186541; called by muse, mutect2, varscan2
- HCN1 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.766); catalogued as rs1060500094, COSV57536554; called by muse, mutect2, varscan2
- HDLBP | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.688); catalogued as COSV100191104; called by muse, mutect2, varscan2
- HERC2 | c.3226G>A p.D1076N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV55322127, COSV99873467; called by muse, mutect2
- HKDC1 | c.384A>T p.E128D | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100664622; called by muse, mutect2, varscan2
- HNF4G | c.62G>A p.G21E (on ENST00000354370 / NM_001330561.2; = p.G68E on NM_004133.5) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62972887; called by muse, mutect2
- HNRNPD | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV100002971; called by muse, mutect2, varscan2
- HNRNPUL2 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1179422398, COSV99584671, COSV99584744; called by muse, mutect2, varscan2
- HOMEZ | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100664130; called by muse, mutect2
- HOOK2 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs759599949, COSV99317664; called by muse, mutect2, varscan2
- HRH4 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56927342; called by muse, mutect2, varscan2
- HSPH1 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748889774, COSV60712426; called by muse, mutect2, varscan2
- HTR3A | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.825); catalogued as COSV100248488; called by muse, mutect2, varscan2
- HTR3B | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.231); catalogued as rs759331217, COSV52747047; called by muse, mutect2, varscan2
- HTR3B | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.906); catalogued as rs1420775583, COSV99492071; called by muse, mutect2
- HTR3C | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as rs960008234, COSV100570668; called by muse, mutect2, varscan2
- HYDIN | c.14974G>A p.E4992K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866011931, COSV66637761; called by muse, mutect2, varscan2
- HYDIN | c.11306G>A p.R3769Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs772896642, COSV66640624; called by muse, mutect2, varscan2
- HYDIN | c.9826C>T p.P3276S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV66889326; called by muse, mutect2, varscan2
- HYDIN | c.5926G>A p.E1976K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as rs866935408, COSV59248601; called by muse, mutect2, varscan2
- IGDCC3 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100031235; called by muse, mutect2
- IGHV3-64 | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs782096889; called by muse, mutect2, varscan2
- IGLV1-44 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); catalogued as rs369507803; called by muse, mutect2, varscan2
- IGSF10 | c.3611C>T p.P1204L | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV56784075; called by muse, mutect2, varscan2
- IL17REL | c.547-2A>C p.X183_splice | Splice Site (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100377295; called by muse, mutect2, varscan2
- IL1B | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99641904; called by muse, mutect2, varscan2
- IL1RL2 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV51820022; called by muse, mutect2, varscan2
- IL36B | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.207); catalogued as rs749951364, COSV52086162, COSV52086587; called by muse, mutect2, varscan2
- IL4R | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV99405138; called by muse, mutect2, varscan2
- IL7R | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57407122; called by muse, mutect2, varscan2
- ILDR1 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56550526, COSV99878480; called by muse, mutect2, varscan2
- INMT | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1242732418, COSV99185049; called by muse, mutect2, varscan2
- INSR | c.3982C>A p.P1328T | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100252592; called by muse, mutect2
- INTU | c.1786T>C p.L596= | Splice Region (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100080995; called by muse, mutect2, varscan2
- IQUB | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as COSV100227192; called by muse, mutect2, varscan2
- ISL1 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100045523; called by muse, mutect2, varscan2
- ITGA2 | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as rs1266385052, COSV99671094; called by muse, mutect2, varscan2
- ITGB4 | c.3031C>T p.P1011S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV99564252; called by muse, mutect2, varscan2
- ITPR3 | c.4100C>T p.S1367F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV65414386; called by muse, mutect2, varscan2
- JAML | c.613C>T p.R205C (on ENST00000356289 / NM_001098526.2; = p.R195C on NM_153206.3) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753962552, COSV52630227; called by muse, mutect2, varscan2
- JPH2 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV65904132; called by muse, mutect2, varscan2
- JPH2 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768672949, COSV65903480; ClinVar: uncertain significance; called by mutect2, varscan2
- KATNAL1 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 78/244 reads (32%) | catalogued as COSV101016982; called by muse, mutect2, varscan2
- KCND2 | c.57G>A p.W19* | Nonsense Mutation (SNP) | VAF 30/167 reads (18%) | catalogued as COSV58569505; called by muse, mutect2, varscan2
- KCNH7 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs139430414; called by muse, mutect2, varscan2
- KCNJ3 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV99716030; called by muse, mutect2, varscan2
- KCNQ3 | c.2324C>T p.S775F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101196223, COSV66463807; called by muse, mutect2, varscan2
- KCNQ5 | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.588); catalogued as COSV59668601; called by muse, mutect2, varscan2
- KCTD19 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100431037; called by muse, mutect2, varscan2
- KCTD8 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as rs1560385987, COSV100759700; called by mutect2, varscan2
- KHDC3L | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1241027501, COSV64863056; called by muse, mutect2, varscan2
- KIAA0319 | c.3003G>A p.M1001I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100985647; called by muse, mutect2, varscan2
- KIAA0895 | c.809C>T p.P270L (on ENST00000297063 / NM_001100425.2; = p.P219L on NM_015314.3) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99766973; called by muse, mutect2, varscan2
- KIAA1217 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs764849456, COSV56814128; called by muse, mutect2, varscan2
- KIR2DL3 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 40/316 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV60895645, COSV60898265; called by muse, varscan2
- KIR3DL1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58494612; called by muse, mutect2, varscan2
- KIR3DL1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as rs1010354695, COSV100428689; called by muse, varscan2
- KIR3DL3 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99399997; called by muse, varscan2
- KLHL38 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.442); catalogued as COSV100384449; called by muse, mutect2, varscan2
- KLHL4 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as COSV64139565; called by muse, mutect2, varscan2
- KLK3 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100386026; called by muse, mutect2, varscan2
- KMT2B | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV52889400; called by muse, mutect2
- KNDC1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58835261; called by muse, mutect2, varscan2
- KRT2 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV59011881; called by muse, mutect2, varscan2
- KRT71 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99922257; called by muse, mutect2, varscan2
- KRT79 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as COSV100398468; called by muse, mutect2, varscan2
- LACTB | c.1444T>C p.Y482H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as COSV99978978; called by muse, mutect2, varscan2
- LAMA3 | c.8018C>T p.A2673V (on ENST00000313654 / NM_198129.4; = p.A1064V on NM_000227.6) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99335162; called by muse, mutect2, varscan2
- LCT | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99929784; called by muse, mutect2, varscan2
- LDHAL6A | c.29A>G p.K10R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV99773132; called by muse, mutect2, varscan2
- LEPR | c.3194G>A p.G1065E | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV62745991; called by muse, mutect2, varscan2
- LETM1 | c.1778C>T p.T593I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV100245500; called by muse, mutect2, varscan2
- LHCGR | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54291907; called by muse, mutect2
- LHX4 | c.1000del p.V334Wfs*15 | Frame Shift Del (DEL) | VAF 96/267 reads (36%) | catalogued as COSV55378102; called by mutect2, pindel, varscan2
- LIFR | c.1192C>T p.Q398* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | catalogued as COSV54697938, COSV99664598; called by muse, mutect2, varscan2
- LIPE | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV99734217; called by muse, mutect2, varscan2
- LIPK | c.633G>A p.M211I | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101344988; called by muse, mutect2, varscan2
- LPA | c.3351G>A p.M1117I | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.06); catalogued as COSV100307287; called by muse, mutect2, varscan2
- LRFN1 | c.1207C>T p.L403F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as COSV99953066; called by muse, mutect2, varscan2
- LRIG2 | c.1655G>T p.W552L | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100743478; called by muse, mutect2, varscan2
- LRIG3 | c.2584G>A p.G862R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100292555, COSV100292696; called by muse, mutect2, varscan2
- LRP11 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.573); catalogued as COSV99497830; called by muse, mutect2, varscan2
- LRP1B | c.11866A>G p.K3956E | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV101257938; called by muse, mutect2, varscan2
- LRP2 | c.2582T>C p.L861P | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV99789165; called by muse, mutect2, varscan2
- LRRC3B | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV67523028; called by muse, mutect2, varscan2
- LRRC66 | c.2165G>A p.R722K | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV100603015; called by muse, mutect2, varscan2
- LSM14B | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs779339184, COSV53380067; called by muse, mutect2, varscan2
- LYPD4 | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100419434; called by muse, mutect2, varscan2
- MAGEC1 | c.502A>C p.S168R | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.815); catalogued as COSV99595960, COSV99596238; called by muse, mutect2, varscan2
- MAGEC1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs866448898, COSV53567920; called by muse, mutect2, varscan2
- MAP1A | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as COSV100288843; called by muse, mutect2
- MAP3K11 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs758480097, COSV58419476; called by muse, mutect2, varscan2
- MAPKBP1 | c.2794C>T p.R932* (on ENST00000456763 / NM_001128608.2; = p.R926* on NM_014994.3) | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV52963266, COSV99529945; called by muse, mutect2, varscan2
- MARK4 | c.1927C>T p.H643Y (on ENST00000262891 / NM_001199867.2; = p.A669= on NM_031417.4) | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99488460; called by muse, mutect2, varscan2
- MAVS | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV100816330; called by muse, mutect2, varscan2
- MBD5 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68698885; called by muse, mutect2, varscan2
- MCF2L | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1193629957, COSV100985689; called by muse, mutect2, varscan2
- MCTP1 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs200393152, COSV100387516; called by muse, mutect2, varscan2
- MED12L | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as rs751524494, COSV99853681; called by muse, mutect2, varscan2
- MED13L | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV99929227; called by muse, mutect2, varscan2
- MED25 | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as COSV100457122; called by muse, mutect2
- MEF2D | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV61727037; called by muse, mutect2, varscan2
- MEP1A | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs1386229821, COSV57919986; called by muse, mutect2
- MET | c.2914G>A p.D972N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs756031094, COSV100577257, COSV59261930; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MGA | c.4352C>T p.P1451L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54961879; called by muse, mutect2, varscan2
- MGAM | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.105); catalogued as COSV72073550; called by muse, mutect2, varscan2
- MID2 | c.2090C>G p.S697C | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV99465001; called by muse, mutect2, varscan2
- MINDY4 | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV54671499, COSV99518888; called by muse, mutect2, varscan2
- MMP13 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99506651; called by muse, mutect2
- MMP27 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV52782340; called by muse, mutect2, varscan2
- MOB3C | c.260G>C p.C87S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99596355; called by muse, mutect2, varscan2
- MPP7 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs868690750, COSV61730420; called by muse, mutect2
- MPST | c.722C>T p.S241F (on ENST00000341116 / NM_001369904.2; = p.S261F on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100353386; called by muse, mutect2, varscan2
- MROH2B | c.2500C>T p.R834W | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368507319; called by muse, mutect2, varscan2
- MROH2B | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as COSV101270697, COSV68180982; called by muse, mutect2, varscan2
- MSR1 | c.425A>G p.Q142R | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs1192721809, COSV100027507; called by muse, mutect2, varscan2
- MTHFD2 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as rs544300372, COSV51201411; called by muse, mutect2, varscan2
- MTMR14 | c.1852C>T p.L618F (on ENST00000296003 / NM_001077525.3; = p.L506F on NM_022485.5) | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.994); catalogued as COSV99931368; called by muse, mutect2, varscan2
- MTNR1A | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV56155323; called by muse, mutect2, varscan2
- MTTP | c.1378G>T p.G460* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV99645322; called by muse, mutect2, varscan2
- MUC16 | c.30740C>T p.P10247L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.389); catalogued as COSV101200297; called by muse, mutect2, varscan2
- MUC16 | c.30019C>T p.P10007S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.094); catalogued as COSV101200299; called by muse, mutect2, varscan2
- MUC16 | c.26512G>A p.D8838N | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.02); catalogued as COSV101200300; called by muse, mutect2, varscan2
- MUC16 | c.21251G>A p.W7084* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as rs750242043, COSV101200303; called by muse, mutect2, varscan2
- MUC16 | c.15355C>T p.P5119S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV67449282; called by muse, mutect2, varscan2
- MUC16 | c.6631C>T p.P2211S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as rs1359261324, COSV101200304; called by muse, mutect2, varscan2
- MUC16 | c.5102C>T p.S1701F | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV101200305; called by muse, mutect2, varscan2
- MYH1 | c.5216C>T p.S1739F | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV56844579; called by muse, mutect2, varscan2
- MYH11 | c.3953A>T p.Q1318L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.875); catalogued as COSV100259414, COSV55560997; called by muse, mutect2, varscan2
- MYH14 | c.4246C>T p.R1416W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1434618100, COSV99223208; called by muse, mutect2, varscan2
- MYH6 | c.4176-1G>A p.X1392_splice | Splice Site (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100676738; called by muse, mutect2, varscan2
- MYH6 | c.2947G>A p.E983K | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100676739; called by muse, mutect2, varscan2
- MYH6 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as rs369931610; called by muse, mutect2, varscan2
- MYO1G | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); catalogued as COSV51856012; called by muse, mutect2, varscan2
- MYOCD | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs139170912; called by mutect2, varscan2
- MYOF | c.2705C>T p.P902L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100825873; called by muse, mutect2, varscan2
- MYT1L | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV101221011; called by muse, varscan2
- MYT1L | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV67709081; called by muse, varscan2
- NBEAL2 | c.4049C>T p.S1350F | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs753738149, COSV99436421; called by muse, mutect2, varscan2
- NDST4 | c.2459G>A p.G820E | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867248758, COSV99996930; called by muse, mutect2, varscan2
- NEBL | c.2425G>A p.V809M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV101009260, COSV101009334; called by muse, mutect2, varscan2
- NEFM | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); catalogued as COSV99647400; called by muse, mutect2, varscan2
- NEUROD1 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54550045; called by muse, mutect2, varscan2
- NFATC2 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs767126542, COSV101044270; called by muse, mutect2, varscan2
- NID2 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV53494815, COSV99356750; called by muse, mutect2, varscan2
- NLN | c.524G>A p.R175K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV101114361; called by muse, mutect2, varscan2
- NLRC5 | c.1543C>T p.L515F | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV99347603; called by muse, mutect2, varscan2
- NLRP1 | c.3301C>T p.H1101Y | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99334549; called by muse, mutect2, varscan2
- NLRP11 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV64086711; called by muse, mutect2, varscan2
- NLRP7 | c.2861T>G p.V954G (on ENST00000340844 / NM_206828.3; = p.V983G on NM_139176.3) | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV100052916; called by muse, mutect2, varscan2
- NLRP9 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as rs773348206, COSV60465119; called by muse, mutect2, varscan2
- NME8 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs151218163, COSV52253530; called by muse, mutect2, varscan2
- NMUR2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775060719, COSV99677028; called by muse, mutect2, varscan2
- NONO | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV52136998, COSV52138484; called by muse, mutect2
- NOS1 | c.2930C>T p.T977I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.245); catalogued as COSV100500841; called by muse, mutect2, varscan2
- NOTCH2 | c.7159C>T p.P2387S | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1193431892, COSV99864971; called by muse, mutect2, varscan2
- NPC1L1 | c.3775G>A p.A1259T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV99212484; called by muse, mutect2, varscan2
- NPHS1 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as rs139472106, COSV100799991; called by muse, mutect2, varscan2
- NRXN1 | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV101277723, COSV68045545; called by muse, mutect2
- NWD1 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.467); catalogued as COSV60337354; called by muse, mutect2, varscan2
- OAS1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as rs1265935047, COSV99177195; called by muse, mutect2, varscan2
- OR10A3 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs751844601, COSV62459225, COSV62459990; called by muse, mutect2, varscan2
- OR10G8 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs745803466, COSV70908204; called by muse, mutect2, varscan2
- OR10H2 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1241642499, COSV59947208; called by muse, mutect2, varscan2
- OR13F1 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100594798; called by muse, mutect2, varscan2
- OR1L1 | c.499G>A p.A167T (on ENST00000373686; = p.A117T on NM_001005236.3) | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs1411482389, COSV58935551; called by muse, mutect2, varscan2
- OR4D10 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101597017; called by muse, mutect2, varscan2
- OR51B2 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767181585, COSV100173414; called by muse, mutect2, varscan2
- OR51F1 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0.055); catalogued as rs867700889, COSV100598820; called by muse, mutect2, varscan2
- OR51L1 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.722); catalogued as COSV100386451; called by muse, mutect2, varscan2
- OR52L1 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV100176224, COSV59989549; called by muse, mutect2
- OR52W1 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100258675; called by muse, mutect2, varscan2
- OR5D13 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs1290933126, COSV100686926; called by muse, mutect2, varscan2
- OR5W2 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60618242; called by mutect2, varscan2
- OR8D4 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.041); catalogued as COSV58430729; called by muse, mutect2, varscan2
- OSBPL6 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.334); catalogued as rs1396980778, COSV99507826; called by muse, mutect2, varscan2
- PACS2 | c.490G>T p.V164F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as COSV100330837, COSV100331142; called by muse, mutect2, varscan2
- PADI1 | c.1705C>G p.P569A | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969154; called by muse, mutect2, varscan2
- PAMR1 | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.034); catalogued as rs1421786914; called by muse, mutect2
- PARP8 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as COSV99891894; called by muse, mutect2, varscan2
- PCARE | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.187); catalogued as COSV100527656; called by muse, mutect2, varscan2
- PCDH15 | c.4565G>A p.R1522K (on ENST00000617271 / NM_001142770.3; = p.K1510= on NM_001142769.3) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | PolyPhen benign (0.006); catalogued as COSV64680988; called by muse, mutect2, varscan2
- PCDH18 | c.2198C>T p.S733F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV61268584; called by muse, mutect2, varscan2
- PCDH18 | c.1532G>A p.G511E | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); catalogued as COSV61267697; called by muse, mutect2
- PCDHA3 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.007); catalogued as rs782260016, COSV65365377, COSV65367658; called by muse, mutect2, varscan2
- PCDHA3 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV63540424; called by muse, mutect2, varscan2
- PCDHAC1 | c.2183G>A p.G728E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99167003; called by muse, mutect2, varscan2
- PCDHAC2 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99150998; called by muse, mutect2, varscan2
- PCDHGA3 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV99541142; called by muse, mutect2, varscan2
- PCDHGA5 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV54048559; called by muse, mutect2, varscan2
- PCDHGB1 | c.1470T>G p.S490R | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99541144; called by muse, mutect2, varscan2
- PCDHGB5 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201599536; called by muse, mutect2, varscan2
- PCLO | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV61680419; called by muse, mutect2, varscan2
- PDE3B | c.2383C>T p.P795S | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.021); catalogued as rs1354424139, COSV99962764; called by muse, mutect2, varscan2
- PDE8B | c.1912G>A p.G638R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.055); catalogued as rs1215492100, COSV99367043; called by muse, mutect2
- PGK2 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as rs185374279, COSV59162850; called by muse, mutect2, varscan2
- PHF8 | c.332A>G p.H111R (on ENST00000357988 / NM_001184896.1; = p.H75R on NM_015107.3) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.045); catalogued as COSV100154431; called by muse, mutect2, varscan2
- PHYHIP | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100395095, COSV100395124; called by muse, mutect2, varscan2
- PID1 | c.211C>T p.P71S (on ENST00000354069 / NM_001330156.1; = p.P69S on NM_017933.5) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs1345703778, COSV100819726; called by muse, mutect2, varscan2
- PIEZO2 | c.8162G>A p.G2721E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99555148; called by muse, mutect2, varscan2
- PKHD1L1 | c.4591A>G p.S1531G | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV101006392; called by muse, mutect2, varscan2
- PLA2R1 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV99323057; called by muse, mutect2, varscan2
- PLCXD3 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV60606911; called by muse, mutect2
- PLXNA4 | c.2662C>T p.R888C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs780941934, COSV58104304; called by muse, mutect2, varscan2
- POF1B | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV53130305, COSV99426031; called by muse, mutect2, varscan2
- POM121 | c.3035C>T p.P1012L (on ENST00000434423; = p.P747L on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs542693697, COSV99988609; called by muse, varscan2
- POTEE | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs1480096738, COSV100388260; called by muse, mutect2
- PPEF2 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs550740753, COSV54422147; called by mutect2, varscan2
- PRDM14 | c.1529A>C p.Q510P | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99400293; called by muse, mutect2, varscan2
- PRDM5 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV99310833; called by mutect2, varscan2
- PRDM9 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs751642339, COSV57013741; called by muse, mutect2, varscan2
- PRLR | c.1067G>A p.S356N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51493975; called by muse, mutect2, varscan2
- PRMT5 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53547385; called by muse, mutect2, varscan2
- PROS1 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs763898193, COSV101260614; called by muse, mutect2, varscan2
- PROX1 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99799679; called by muse, mutect2, varscan2
- PRR30 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV99574590; called by muse, mutect2
- PRRC2B | c.5693C>T p.S1898F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV100261045; called by muse, mutect2, varscan2
- PRRG1 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.809); catalogued as COSV66158761; called by muse, mutect2, varscan2
- PSG4 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV99737322; called by muse, mutect2, varscan2
- PSG5 | c.695C>T p.T232I | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as rs1568371912, COSV61654901; called by muse, mutect2, varscan2
- PSG7 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV101343280; called by muse, mutect2, varscan2
- PSG8 | c.1217C>A p.S406Y | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs891936994, COSV60611646; called by muse, mutect2, varscan2
- PTPRB | c.4780G>T p.E1594* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV54241290, COSV99717903; called by muse, mutect2, varscan2
- PTPRD | c.5410C>T p.Q1804* | Nonsense Mutation (SNP) | VAF 59/128 reads (46%) | catalogued as COSV61938609; called by muse, mutect2, varscan2
- PTPRK | c.2890G>A p.E964K (on ENST00000368215 / NM_001291984.2; = p.E965K on NM_002844.4) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs868817217, COSV100951308; called by muse, mutect2, varscan2
- PTPRK | c.2357C>T p.A786V (on ENST00000368215 / NM_001291984.2; = p.A787V on NM_002844.4) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV63903024; called by muse, mutect2
- PTPRT | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.789); catalogued as COSV100628381, COSV61977469; called by muse, mutect2, varscan2
- PTPRZ1 | c.5290C>T p.H1764Y | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101100348; called by muse, mutect2
- PZP | c.2008G>A p.G670R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99738410; called by muse, mutect2, varscan2
- RAE1 | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as COSV100982446; called by muse, mutect2, varscan2
- RAI1 | c.2885C>T p.P962L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.039); catalogued as rs1198795075, COSV99884373; called by muse, mutect2, varscan2
- RALGAPA1 | c.451T>C p.F151L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99355217; called by muse, mutect2, varscan2
- RAPGEF5 | c.1096G>A p.E366K (on ENST00000401957 / NM_001367602.2; = p.E669K on NM_012294.5) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59783121; called by muse, mutect2
- RBM27 | c.2422G>A p.D808N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV99506307; called by muse, mutect2, varscan2
- RELN | c.8183G>A p.G2728D | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs757194948, COSV100633937, COSV100634073; called by muse, mutect2, varscan2
- RELN | c.1896G>A p.W632* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100634074; called by muse, mutect2, varscan2
- RERGL | c.70T>C p.F24L | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV99967968; called by muse, mutect2, varscan2
- RESF1 | c.584T>C p.V195A | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as COSV100440416; called by muse, mutect2, varscan2
- RFPL2 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV50713647; called by muse, mutect2, varscan2
- RFPL3 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.139); catalogued as rs775799598, COSV99967152; called by muse, mutect2, varscan2
- RHOBTB1 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV61958544; called by muse, varscan2
- RIMS2 | c.1441G>A p.D481N (on ENST00000666250 / NM_001348490.2; = p.D289N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99173196; called by muse, mutect2, varscan2
- RIN3 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV99379476; called by muse, mutect2
- RNF150 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV100153720, COSV100153881; called by muse, mutect2, varscan2
- ROBO2 | c.3403C>T p.R1135* | Nonsense Mutation (SNP) | VAF 28/74 reads (38%) | catalogued as COSV59899491; called by muse, mutect2, varscan2
- RP1 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs751050043, COSV99607929; called by muse, mutect2, varscan2
- RP1 | c.1555C>T p.Q519* | Nonsense Mutation (SNP) | VAF 24/41 reads (59%) | catalogued as rs1554519459, COSV99607933; called by muse, mutect2, varscan2
- RPGRIP1 | c.2612C>T p.S871F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.401); catalogued as rs780497273, COSV52845419; called by muse, mutect2, varscan2
- RPS6KA2 | c.1412C>T p.T471I | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99691311; called by muse, mutect2, varscan2
- RRBP1 | c.2668G>A p.E890K (on ENST00000377813 / NM_001365613.2; = p.E457K on NM_004587.3) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99854211; called by muse, mutect2
- RSPH10B | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100521337; called by mutect2, varscan2
- RSPH14 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99320918; called by muse, mutect2, varscan2
- RTN1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as rs866220256, COSV50756561, COSV99955278; called by muse, mutect2, varscan2
- RTN2 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99839039; called by muse, mutect2, varscan2
- RTTN | c.4093C>G p.Q1365E | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as COSV99732859; called by muse, mutect2, varscan2
- RXYLT1 | c.836A>T p.N279I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99706986; called by muse, mutect2, varscan2
- S1PR5 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100330775; called by mutect2, varscan2
- SALL2 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs756058987, COSV58105851; called by muse, mutect2, varscan2
- SAMD7 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV59420645; called by muse, mutect2, varscan2
- SASS6 | c.1663T>A p.S555T | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.027); catalogued as COSV99790926; called by muse, mutect2, varscan2
- SCARB2 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99357995; called by muse, mutect2
- SCN11A | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs376641599, COSV56566299; called by muse, mutect2, varscan2
- SCN1A | c.3049G>A p.D1017N (on ENST00000303395 / NM_001202435.3; = p.D1006N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV100320942; called by muse, mutect2
- SCN3A | c.5551G>A p.D1851N | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99327444; called by muse, mutect2, varscan2
- SCN3A | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV99327446; called by muse, mutect2, varscan2
- SCN7A | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101313103, COSV101313278; called by muse, mutect2, varscan2
- SCNN1A | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV57434908, COSV99964796; called by muse, mutect2
- SCYL1 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54212148; called by muse, mutect2, varscan2
- SDAD1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as rs754724162, COSV62402389; called by muse, mutect2, varscan2
- SEC14L5 | c.1420C>T p.L474F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV52043500; called by muse, mutect2, varscan2
- SEMA3A | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1292377214, COSV99547159; called by muse, mutect2, varscan2
- SEMG2 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.459); catalogued as COSV101034136; called by muse, mutect2, varscan2
- SEPTIN4 | c.1304T>C p.V435A | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.042); catalogued as COSV100400377; called by muse, mutect2, varscan2
- SERPINA7 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59664893; called by muse, mutect2, varscan2
- SERPINB11 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1355365574, COSV66956404; called by muse, mutect2, varscan2
- SERPINB4 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs764188105, COSV61984169; called by muse, mutect2, varscan2
- SERPINE1 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.843); catalogued as COSV99776750; called by muse, mutect2, varscan2
- SERPINI2 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 34/80 reads (43%) | catalogued as rs898055782, COSV52984863, COSV52987626; called by muse, mutect2, varscan2
- SESTD1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101468144, COSV70567330; called by muse, mutect2, varscan2
- SETD4 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV100145663; called by muse, mutect2
- SETD7 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as rs1177821925, COSV99918554; called by muse, mutect2, varscan2
- SGIP1 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99391968; called by muse, mutect2, varscan2
- SH3RF2 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752118032, COSV100767843; called by muse, mutect2, varscan2
- SHROOM3 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99934657; called by muse, mutect2
- SIAE | c.1229A>G p.E410G | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV99422545; called by muse, mutect2, varscan2
- SIM1 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.224); catalogued as COSV99492446; called by muse, mutect2, varscan2
- SIPA1L1 | c.3809C>T p.S1270F | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs1169122423, COSV100665686; called by muse, mutect2, varscan2
- SIRPG | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 27/118 reads (23%) | catalogued as rs763356667, COSV53806812; called by muse, mutect2, varscan2
- SLC1A2 | c.1427G>A p.R476K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99554473, COSV99554693; called by muse, mutect2, varscan2
- SLC20A2 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV60601363; called by muse, mutect2, varscan2
- SLC22A5 | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.052); catalogued as COSV55374777; called by muse, mutect2, varscan2
- SLC22A8 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs1402062009, COSV100267944; called by muse, mutect2, varscan2
- SLC24A2 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53868785, COSV53873444; called by muse, mutect2, varscan2
- SLC24A2 | c.1133G>A p.R378K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99646882; called by muse, mutect2
- SLC24A3 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.766); catalogued as COSV100041694; called by muse, mutect2, varscan2
- SLC25A21 | c.786G>A p.G262= | Splice Region (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100491541; called by muse, mutect2, varscan2
- SLC43A1 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV99561070; called by muse, mutect2, varscan2
- SLC44A1 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV100570512; called by muse, mutect2, varscan2
- SLC44A5 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100902192; called by muse, mutect2, varscan2
- SLC44A5 | c.854-1G>A p.X285_splice | Splice Site (SNP) | VAF 17/37 reads (46%) | catalogued as COSV100902193; called by muse, mutect2, varscan2
- SLC4A11 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV101196040; called by muse, mutect2, varscan2
- SLC5A7 | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as rs868575792, COSV99886856; called by muse, mutect2, varscan2
- SLC8A3 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100776271; called by muse, mutect2, varscan2
- SLC8A3 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63523816; called by muse, mutect2, varscan2
- SLCO4C1 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV60514582; called by muse, mutect2, varscan2
- SLCO4C1 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1165732807, COSV60512796; called by muse, mutect2, varscan2
- SLX4IP | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100570589, COSV57947192; called by muse, mutect2, varscan2
- SMR3A | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.64); catalogued as COSV99895731; called by muse, varscan2
- SMR3A | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); catalogued as COSV56950234; called by muse, varscan2
- SNAP91 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99535645; called by muse, mutect2
- SNRNP200 | c.4235C>T p.T1412I | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV100107727; called by muse, mutect2, varscan2
- SORBS2 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.48); catalogued as COSV99511507; called by muse, mutect2, varscan2
- SOX9 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.915); catalogued as COSV99818538; called by muse, mutect2, varscan2
- SP2 | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV100947232; called by muse, mutect2, varscan2
- SPATA18 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99730732; called by muse, mutect2, varscan2
- SPATA18 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs750901784, COSV54650122; called by muse, mutect2, varscan2
- SPATA31A3 | c.3175C>T p.Q1059* | Nonsense Mutation (SNP) | VAF 38/154 reads (25%) | catalogued as rs776932511; called by muse, varscan2
- SPDYA | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs771698422, COSV61856457; called by mutect2, varscan2
- SPHKAP | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV60882570, COSV60896018; called by muse, mutect2, varscan2
- SPINK13 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV101268306; called by muse, varscan2
- SPINK6 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100347126; called by muse, mutect2, varscan2
- SPOCK3 | c.710A>T p.E237V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV100693254, COSV62730941; called by muse, mutect2, varscan2
- SPTLC3 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV100983209, COSV100983325; called by muse, mutect2, varscan2
- SRC | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100658112; called by muse, mutect2, varscan2
- ST8SIA4 | c.211T>C p.W71R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | PolyPhen benign (0.261); catalogued as COSV99185355; called by muse, mutect2, varscan2
- STAB2 | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs759885088, COSV66349548; called by muse, mutect2
- STX1A | c.121C>G p.R41G | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99767510; called by muse, mutect2
- SULT1E1 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV56947621; called by mutect2, varscan2
- SUPT16H | c.1511+2T>G p.X504_splice | Splice Site (SNP) | VAF 22/70 reads (31%) | catalogued as COSV99359970; called by muse, mutect2, varscan2
- SYNE1 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.229); catalogued as rs1265158073, COSV99569208; called by muse, varscan2
- SYTL4 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99343019; called by muse, mutect2, varscan2
- TACC2 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); catalogued as COSV100552700; called by muse, mutect2, varscan2
- TAS2R9 | c.798T>G p.I266M | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV99553850; called by muse, mutect2, varscan2
- TAS2R9 | c.266G>A p.W89* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as rs750159262, COSV99553851; called by muse, mutect2, varscan2
- TBC1D1 | c.2430G>A p.W810* | Nonsense Mutation (SNP) | VAF 23/119 reads (19%) | catalogued as COSV99791538; called by muse, mutect2, varscan2
- TBC1D22B | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV65143813; called by muse, mutect2, varscan2
- TBC1D25 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.32); catalogued as rs782558791, COSV100952183; called by muse, mutect2, varscan2
- TBCE | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.628); catalogued as COSV100783146; called by muse, mutect2, varscan2
- TBX15 | c.1771C>T p.P591S (on ENST00000369429 / NM_001330677.2; = p.P485S on NM_152380.3) | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.08); catalogued as COSV99253463, COSV99254314; called by muse, mutect2, varscan2
- TBX15 | c.1126C>T p.H376Y (on ENST00000369429 / NM_001330677.2; = p.H270Y on NM_152380.3) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV52870399; called by muse, mutect2, varscan2
- TCF4 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100610432; called by muse, varscan2
- TCL1A | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101268469; called by muse, mutect2, varscan2
- TECRL | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101169083; called by muse, mutect2, varscan2
- TENM4 | c.7468C>T p.P2490S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV99575934; called by muse, mutect2
- TET1 | c.3119C>T p.P1040L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV65388824; called by muse, mutect2, varscan2
- TFF1 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs150281749; called by muse, mutect2, varscan2
- THSD7A | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs1323213823, COSV101448783; called by muse, varscan2
- THSD7B | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV99753342; called by muse, mutect2, varscan2
- TLL1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV50303936; called by muse, mutect2, varscan2
- TLR1 | c.2281G>A p.E761K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58304107; called by muse, varscan2
- TMBIM4 | c.680A>G p.H227R | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV53969520; called by muse, mutect2, varscan2
- TMEM132B | c.2470C>T p.Q824* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100170112; called by muse, mutect2, varscan2
- TMEM132B | c.2980C>T p.H994Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV54754362; called by muse, mutect2, varscan2
- TMEM178A | c.484A>C p.T162P | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV99931943; called by muse, mutect2, varscan2
- TMEM200A | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99759503; called by muse, mutect2, varscan2
- TMEM74 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99865736; called by muse, mutect2, varscan2
- TMPRSS4 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV71110951; called by muse, mutect2, varscan2
- TNRC6B | c.1334A>G p.N445S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.952); catalogued as COSV100109931; called by muse, mutect2
- TOGARAM2 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV101091222; called by muse, mutect2, varscan2
- TOPORS | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1180548820, COSV100745184, COSV100745188; called by muse, mutect2, varscan2
- TRIM55 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52543334; called by muse, mutect2, varscan2
- TRIML1 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV100206104; called by muse, mutect2, varscan2
- TRPC6 | c.1595G>A p.G532D | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100723669; called by muse, mutect2, varscan2
- TSBP1 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.853); catalogued as COSV66660625; called by muse, mutect2, varscan2
- TSPAN12 | c.739G>C p.A247P | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV99763245; called by muse, mutect2
- TSPAN12 | c.737G>A p.W246* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV56078921, COSV99763247; called by muse, mutect2
- TSPAN16 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.096); catalogued as COSV100368389; called by muse, mutect2, varscan2
- TTC7A | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV99766579; called by muse, mutect2, varscan2
- TTC7A | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs752771480, COSV99766582; called by muse, mutect2, varscan2
- TTC7B | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1326650051, COSV100128105; called by muse, mutect2, varscan2
- TTLL4 | c.2819C>T p.P940L | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99293436; called by muse, mutect2, varscan2
- TTN | c.74069G>A p.R24690Q (on ENST00000591111; = p.R17266Q on NM_003319.4) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | PolyPhen probably damaging (0.996); catalogued as rs758190406, COSV60188912; called by muse, mutect2, varscan2
- TTN | c.69853G>A p.E23285K (on ENST00000591111; = p.E15861K on NM_003319.4) | Missense Mutation (SNP) | VAF 14/107 reads (13%) | PolyPhen benign (0.142); catalogued as COSV59926997; called by muse, mutect2, varscan2
- TTN | c.53960T>G p.V17987G (on ENST00000591111; = p.V10563G on NM_003319.4) | Missense Mutation (SNP) | VAF 20/117 reads (17%) | PolyPhen benign (0.242); catalogued as COSV100618718; called by muse, mutect2, varscan2
- TTN | c.34133C>T p.P11378L (on ENST00000591111; = p.P10451L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | PolyPhen benign (0.085); catalogued as COSV100618725; called by muse, mutect2
- TTN | c.16533A>C p.E5511D (on ENST00000591111; = p.E4584D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/117 reads (21%) | PolyPhen benign (0.291); catalogued as COSV100618733; called by muse, mutect2, varscan2
- TTN | c.16369G>A p.D5457N (on ENST00000591111; = p.D4530N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | PolyPhen benign (0.001); catalogued as rs752660722, COSV60026502; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.2995C>T p.R999C (on ENST00000591111; = p.R953C on NM_003319.4) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | PolyPhen probably damaging (0.966); catalogued as rs142000511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | PolyPhen probably damaging (0.996); catalogued as COSV100618750; called by muse, mutect2, varscan2
- TTN | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 27/97 reads (28%) | PolyPhen possibly damaging (0.688); catalogued as rs754182768, COSV60080671; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXNDC2 | c.841G>A p.E281K (on ENST00000306084 / NM_001098529.2; = p.E214K on NM_032243.6) | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV100046297; called by muse, mutect2, varscan2
- UBR5 | c.2971A>T p.M991L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV99641310; called by muse, mutect2, varscan2
- UCHL3 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV101111553; called by muse, mutect2, varscan2
- UGT2A2 | c.311T>G p.I104S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV99684536; called by muse, mutect2, varscan2
- UGT2B11 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.718); catalogued as rs778246996, COSV71423067; called by muse, mutect2, varscan2
- UGT2B17 | c.1571G>A p.G524E | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.92); catalogued as COSV100497243; called by muse, mutect2, varscan2
- UGT2B28 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV59431371; called by muse, mutect2, varscan2
- UGT2B4 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553895303, COSV100522492; called by muse, mutect2, varscan2
- UNC13C | c.1972A>G p.K658E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as COSV99519435; called by muse, mutect2, varscan2
- USH1C | c.39G>A p.V13= | Splice Region (SNP) | VAF 11/49 reads (22%) | catalogued as COSV50032758, COSV99140485; called by muse, mutect2, varscan2
- USHBP1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99394350; called by muse, mutect2, varscan2
- USP20 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); catalogued as rs991052449, COSV100204430; called by muse, mutect2, varscan2
- USP35 | c.1192A>T p.I398F | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV101489111; called by muse, mutect2, varscan2
- USP6 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.918); catalogued as COSV100004315; called by muse, mutect2, varscan2
- VN1R2 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100448025; called by muse, mutect2, varscan2
- VPS50 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.034); catalogued as COSV100004961; called by muse, mutect2, varscan2
- WAS | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM043608, CM043609, CM951322, COSV100939506; called by muse, mutect2
- WDR17 | c.3926C>T p.P1309L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV54584617; called by muse, mutect2, varscan2
- WDR36 | c.59T>G p.V20G | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV101540810; called by muse, mutect2, varscan2
- WDR6 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as COSV100556523; called by muse, mutect2
- WDR93 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99175673; called by muse, mutect2, varscan2
- XIRP2 | c.4735G>A p.A1579T (on ENST00000628543; = p.A1754T on NM_152381.6) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99744345; called by muse, mutect2, varscan2
- XIRP2 | c.6134C>T p.S2045F (on ENST00000628543; = p.S2220F on NM_152381.6) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs1378068122, COSV99744347; called by muse, mutect2
- XIRP2 | c.6617C>T p.S2206F (on ENST00000628543; = p.S2381F on NM_152381.6) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.64); catalogued as COSV99744350; called by muse, mutect2, varscan2
- XKR4 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59301592; called by muse, mutect2, varscan2
- ZAN | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV100769871; called by muse, mutect2, varscan2
- ZBED2 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.505); catalogued as COSV99343081; called by muse, mutect2, varscan2
- ZDBF2 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100985065; called by muse, mutect2, varscan2
- ZDBF2 | c.6449T>G p.F2150C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.547); catalogued as COSV100985068; called by muse, mutect2, varscan2
- ZDHHC2 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100024943; called by muse, mutect2
- ZEB1 | c.1523T>C p.L508S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV100314591; called by muse, mutect2, varscan2
- ZFHX4 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.024); catalogued as COSV50630013; called by mutect2, varscan2
- ZFP2 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as rs759706434, COSV100796977, COSV63726956; called by muse, mutect2, varscan2
- ZFPM2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV101023073; called by muse, mutect2, varscan2
- ZFR2 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.9); PolyPhen benign (0.176); catalogued as rs374607467; called by muse, varscan2
- ZNF17 | c.782T>C p.V261A | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs1480228775, COSV100300083; called by muse, mutect2, varscan2
- ZNF208 | c.3797C>T p.S1266L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV101237073, COSV101237186; called by muse, mutect2, varscan2
- ZNF256 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99990900; called by muse, mutect2, varscan2
- ZNF280A | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV57482759; called by muse, mutect2, varscan2
- ZNF334 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV100749096; called by muse, mutect2
- ZNF438 | c.1874+2T>G p.X625_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100062186; called by muse, mutect2
- ZNF471 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57291666; called by muse, mutect2, varscan2
- ZNF519 | c.607C>T p.H203Y | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as COSV101645577, COSV101645607; called by muse, mutect2, varscan2
- ZNF528 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.321); catalogued as COSV100846686; called by muse, mutect2, varscan2
- ZNF597 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57084797, COSV57085175; called by muse, mutect2, varscan2
- ZNF608 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.117); catalogued as COSV100101021; called by muse, mutect2, varscan2
- ZNF648 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV100374664; called by muse, mutect2, varscan2
- ZNF676 | c.1570C>T p.L524F (on ENST00000650058; = p.L492F on NM_001001411.3) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as rs199536409, COSV101236254, COSV101236390; called by muse, mutect2, varscan2
- ZNF704 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.116); catalogued as COSV59923136; called by muse, mutect2
- ZNF711 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99341267; called by muse, mutect2
- ZNF804A | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs202247802, COSV56436947, COSV56445554; called by muse, mutect2, varscan2
- ZNF804B | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100304473; called by muse, mutect2
- ZNF831 | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100926023, COSV64038770; called by muse, mutect2, varscan2
- ZNF831 | c.4975C>T p.R1659* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as rs753171906, COSV64045754; called by muse, mutect2, varscan2
- ZNF875 | c.417T>A p.F139L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100183392; called by muse, mutect2, varscan2
- AC092143.1 | c.1463dup p.G489Rfs*16 | Frame Shift Ins (INS) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- CSDE1 | c.712-17_724del p.X238_splice (on ENST00000358528 / NM_001007553.3; = p.X207_splice on NM_007158.6) | Splice Site (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- FANCD2 | c.519_525del p.R174Lfs*5 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- HELZ2 | c.7220del p.D2407Afs*38 (on ENST00000467148 / NM_001037335.2; = p.D1838Afs*38 on NM_033405.3) | Frame Shift Del (DEL) | VAF 41/122 reads (34%) | called by mutect2, pindel, varscan2
- IGHM | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- IGHV1-45 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- IGHV1-58 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- IGHV3-73 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- IGKV1-12 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.152); called by mutect2, varscan2
- OR5T3 | c.787dup p.Y263Lfs*21 | Frame Shift Ins (INS) | VAF 21/99 reads (21%) | called by mutect2, pindel, varscan2
- OSBPL1A | c.2547del p.F849Lfs*8 (on ENST00000319481 / NM_080597.4; = p.F336Lfs*8 on NM_018030.4) | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- PARP8 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- TRAV13-2 | c.20T>C p.L7S | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- A1CF | c.1284G>A p.G428= (on ENST00000373993 / NM_138932.2; = p.G420= on NM_014576.4) | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV99256779; called by muse, mutect2
- AADAC | c.420C>T p.V140= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs1301322001, COSV51758402; called by muse, mutect2, varscan2
- ABCA8 | c.4287G>A p.R1429= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV52203395; called by muse, mutect2, varscan2
- ABCC9 | c.2434C>T p.L812= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as rs1387288336, COSV99686141; called by muse, mutect2, varscan2
- ACAN | c.7080G>A p.E2360= (on ENST00000560601 / NM_001369268.1; = p.E2284= on NM_001135.3) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs534424968, COSV100718431; called by muse, mutect2, varscan2
- ACSM2A | c.1545C>T p.F515= (on ENST00000219054; = p.F436= on NM_001308169.2) | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV54581729; called by muse, mutect2, varscan2
- ACSM5 | c.994C>T p.L332= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as COSV100089076; called by muse, mutect2, varscan2
- ACTL7A | c.1068G>A p.G356= | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as rs750011882, COSV100453152; called by muse, mutect2, varscan2
- ADAM18 | c.1896G>A p.G632= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99695789; called by muse, mutect2, varscan2
- ADCY8 | c.3678C>T p.N1226= | Silent (SNP) | VAF 51/119 reads (43%) | catalogued as COSV53904282; called by muse, mutect2, varscan2
- ADCY8 | c.3474C>T p.I1158= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV99652854; called by muse, mutect2
- ADGRL2 | c.2997C>T p.T999= (on ENST00000370717 / NM_001366005.1; = p.T986= on NM_012302.4) | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs996064009, COSV99589797; called by muse, mutect2, varscan2
- AFF2 | c.3852G>A p.L1284= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV99664754, COSV99666346; called by muse, mutect2, varscan2
- AK9 | c.243A>C p.S81= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV99572606; called by muse, mutect2, varscan2
- AL121899.2 | c.762G>A p.G254= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV67350723; called by muse, mutect2, varscan2
- ANK1 | c.867G>A p.E289= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV99225714; called by muse, mutect2, varscan2
- ANK2 | c.6105G>A p.P2035= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs757880191, COSV100002412; called by muse, mutect2, varscan2
- ANKS4B | c.405G>A p.L135= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs752698422, COSV61139639; called by muse, mutect2, varscan2
- ANO1 | c.465T>C p.F155= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100304147; called by muse, mutect2
- ANXA10 | c.120G>A p.L40= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV63739458; called by muse, mutect2, varscan2
- ARAP2 | c.3867A>T p.L1289= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100394864; called by muse, mutect2, varscan2
- ARFGEF2 | c.5094C>T p.I1698= | Silent (SNP) | VAF 61/197 reads (31%) | catalogued as rs143470429; called by muse, mutect2, varscan2
- ARHGAP20 | c.1671C>T p.S557= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs1265088324, COSV99504489; called by muse, mutect2, varscan2
350 further variants in this file (0 protein-altering or splice-affecting, 326 silent, 24 other) are not listed here.
